Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8368, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8368-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]	Case ID	Gross Description	Microscopic Description
[REDACTED]	[REDACTED]	Stomach segment with a plate-like tumour of 6 cm in the largest dimension, with invasion of the all layers. Fatty tissue lymph nodes are dense, hyperemic. Omentum - hyperemia.	Adenocarcinoma of the stomach, G3; with focal mucin production and focal necrosis. There is an invasion into the muscularis propria. Fifteen examined lymph nodes demonstrated reactive hyperplasia, hyperemia. Omentum - haemorrhages.

[page 2 of 3]
Diagnosis Details	Comments	Formatted Path Report
Tumor Features: Ulcerated, Tumor Extent: Muscularis propria, Venous Invasion: Absent, Margins: Absent, Treatment Effect:		STOMACH TISSUE CHECKLIST Specimen type: Subtotal gastrectomy Tumor site: Fundus Tumor size: 6 x 0 x 0 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Muscularis propria Lymph nodes: 0/15 positive for metastasis (Greater and lesser omentum 0/15) Lymphatic invasion: Not specified Venous invasion: Absent Perineural invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 3 of 3]
	ID	Excision Date	Laterality

Source: NCI Genomic Data Commons file a4f54bba-f314-4249-9ca2-06982b345d03 (TCGA-BR-8368.5836D843-39FD-4C25-A740-124E59E31907.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).